Gene-level copy-number profile of tumor specimen TCGA-E5-A4U1-01A from TCGA case TCGA-E5-A4U1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 72.0 years (26,305 days).
Specimen TCGA-E5-A4U1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6f5cb537-831d-4c54-b181-b6630fd1f71f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E5-A4U1-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4cef9a87-8431-4f22-a912-c7ec661a89e5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 494; copy number 2: 12,136; copy number 3: 27,677; copy number 4: 11,930; copy number 5: 2,784; copy number 6: 3,646; copy number 7: 516; copy number 8: 173; copy number 9: 168; copy number 10: 99; copy number 11: 13; copy number 12: 1; copy number 13: 12; copy number 14: 8; copy number 16: 28; copy number 18: 33; copy number 23: 14; copy number 27: 41; copy number 30: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E5-A4U1-01A-11D-A31K-01): tumor purity 0.78, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–116,850,367, 1 gene: MIR4447.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,135 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,081,316–42,164,745, 95 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr1:158,610,704–170,370,367, 336 genes, copy number 7–13 (within-gene range 4–13) (broad region; genes not listed).
- chr4:1,617,915–1,856,156, 8 genes, copy number 9 (within-gene range 4–9): FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1.
- chr4:70,518,569–71,572,087, 18 genes, copy number 8 (within-gene range 6–8): AMTN, AMBN, ENAM, AC009570.2, JCHAIN, UTP3, RNU6-520P, RNU6-784P, AC009570.1, RUFY3, GRSF1, U6, RNU6-891P, MOB1B, DCK, SLC4A4, AC096713.1, LDHAL6EP.
- chr5:99,489,559–108,593,967, 77 genes, copy number 8–23 (broad region; genes not listed).
- chr5:111,912,508–121,060,953, 121 genes, copy number 8–18 (within-gene range 5–18) (broad region; genes not listed).
- chr5:121,195,980–121,196,210, 1 gene, copy number 8: AC010350.1.
- chr5:129,094,749–130,186,634, 12 genes, copy number 7: ISOC1, MIR4633, AC008679.1, MIR4460, ADAMTS19-AS1, ADAMTS19, AC008591.1, MINAR2, CHSY3, RNU6ATAC10P, RNA5SP191, HSPA8P4.
- chr5:136,132,845–136,193,162, 2 genes, copy number 8: SMAD5, SMIM32.
- chr7:29,806,486–31,119,572, 41 genes, copy number 8: WIPF3, AC004912.1, SCRN1, FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1, AC006978.2, AC006978.1, LINC01176, NOD1, AC006027.1, GGCT, AC005154.5, GARS1-DT, AC005154.2, AC005154.4, AC005154.1, AC005154.3, GARS1, CRHR2, INMT, AC006022.1, INMT-MINDY4, MINDY4, AC004691.1, AC004691.2, AQP1, GHRHR, ADCYAP1R1, AC006466.1.
- chr7:31,751,179–36,320,479, 79 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr7:42,794,906–42,802,494, 1 gene, copy number 9: TCP1P1.
- chr7:50,839,363–51,316,818, 6 genes, copy number 9: AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2.
- chr11:68,870,664–69,775,341, 29 genes, copy number 30: LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4.
- chr11:72,285,495–74,254,703, 66 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:76,591,023–79,612,300, 66 genes, copy number 10–27 (broad region; genes not listed).
- chr16:20,451,461–23,216,883, 86 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr16:50,727,417–50,901,063, 8 genes, copy number 7: AC007728.2, CYLD, MIR3181, AC007728.1, LINC02168, LINC02128, AC025810.1, RNA5SP426.
- chr19:6,729,914–7,903,542, 61 genes, copy number 8 (broad region; genes not listed).
- chr19:9,291,140–9,498,616, 10 genes, copy number 7 (within-gene range 6–7): ZNF699, AC011451.1, ZNF559, ZNF559-ZNF177, AC011451.2, ZNF177, AC011451.3, ZNF266, AC011451.4, ZNF560.
- chr20:257,724–462,543, 12 genes, copy number 8: DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
